CCDI case PBCSSR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c307b3f4-58d6-4f08-b8c6-2559e982494d

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Teratoma, NOS: ICD-O-3 morphology code: 9080/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 11.4 years (4,153 days).

Biospecimens (2 samples)
- Sample 0DYJ1X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYJ24: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
